Somatic mutation profile of tumor specimen BA2232D (aliquot aq-BA2232D) from BEATAML1.0 case 2523, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.8 years (27,324 days).
Specimen BA2232D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59c11588-7408-47d6-b9e1-4416815f2886.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2527D (Solid Tissue Normal), aliquot aq-BA2527D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbe0e15f-77de-4c91-a232-b2cdce60362d

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, 3'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM132B | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753441483, COSV54768026; called by muse, mutect2, varscan2
- ATL2 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- BICRA | c.1301C>A p.A434E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2
- ESPL1 | c.2015A>G p.Q672R | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGF2R | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- KCNB2 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- KMT2B | c.4784C>A p.A1595E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); called by muse, mutect2
- PTCHD3 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2
- SLC35A2 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZIC1 | c.1104C>A p.D368E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2
- APLP1 | c.921C>T p.H307= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs751432524, COSV55707553; called by muse, mutect2, varscan2
- CACNA1H | c.354C>A p.G118= | Silent (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- CCDC183 | c.561C>A p.P187= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- EPHX1 | c.726C>T p.H242= | Silent (SNP) | VAF 96/226 reads (42%) | catalogued as rs779393301; called by muse, mutect2, varscan2
- GPR179 | c.4884G>A p.S1628= (on ENST00000621958; = p.S1627= on NM_001004334.4) | Silent (SNP) | VAF 100/224 reads (45%) | catalogued as rs373824707; called by muse, varscan2
- LGALS3 | c.564G>A p.S188= | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as rs965410154; called by muse, mutect2, varscan2
- FAM27E5 | n.460G>A | RNA (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.*324G>A | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791868 C>T | 3'Flank (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
